Clinical report (de-identified scan), EXCEPTIONAL_RESPONDERS case ER-B1T5, project EXCEPTIONAL_RESPONDERS-ER (Exceptional Responders), specimen ER-B1T5-TTP1-B (Slides).

[page 1 of 16]
[REDACTED]

[REDACTED]

[REDACTED] +53

PATHOLOGY SURGICAL

Results

Status: Final result (Collected: [REDACTED] +406

Specimen Information

Collected: [REDACTED] +406

Component

PATHOLOGY RESULT

[page 2 of 16]
Component

PATH # [REDACTED]
SPECIMEN DATE: [REDACTED] +41
SUBMITTING MD: [REDACTED]
Department of Pathology
[REDACTED]

Final

Clinical Data Repository* This report may not match the original report
format
REPORT DATE: [REDACTED] +45

FINAL DIAGNOSIS

(OS Case# [REDACTED]
[REDACTED]
+9

A. (Left breast at 2:00, 7 cm from nipple; biopsy):
Invasive ductal carcinoma, grade 3.
See note.

B. (Left breast at 2:00, 7 cm from nipple; biopsy):
Invasive ductal carcinoma, grade 3.
See note.

Attending Pathologist: [REDACTED] * Electronically signed Pathology
Resident: [REDACTED]

NOTE

A. BREAST MARKERS AS FOLLOWS:

ER(SP1, FLEX+): Positive (>90%)

PR(PgR636, FLEX+): Negative (0%)

HER-2/neu(HercepTest): will be reported in an addendum

FISH RESULTS

There is amplification of the HER-2 /neu gene as determined by FISH,
(PathVysion [REDACTED] assay). The ratio of the number of copies of the
HER-2/neu
gene to the centromeric probe for chromosome 17 is approximately 5. A
minimum of 25 cells were counted.

The PathVysion assay kit by [REDACTED] is approved by FDA for HER-2 FISH

[page 3 of 16]
Component
assay.

All tissue used to provide diagnostic predictive information is fixed in 10% neutral buffered formalin and processed in paraffin.

Results reported as HER-2/neu: chromosome 17 centromere probe signal ratio

Reference Range(s)

Not amplified less than 1.8
Equivocal 1.8-2.2
Amplified greater than 2.2

Breast Marker Reference Ranges

Marker	Negative	Positive	
ER	<1%	1% or higher	
PR	<1%	1% or higher	
Her-2/neu	0 or 1+	2+ or 3+	
EGFR	<10%	10% or higher	
Marker	Unfavorable	Intermediate	Favorable
MIB-1 (Ki-67)	>20%	10% to 20%	<10%

All tissue submitted to provide diagnostic predictive information is fixed in
10% neutral buffered formalin and processed in paraffin.

Immunohistochemistry controls are examined and show appropriate reactivity.

B. BREAST MARKERS AS FOLLOWS:

ER(SP1, FLEX+): Positive (90%)

PR(PgR636, FLEX+): Negative (0%)

HER-2/neu(HercepTest): will be reported in an addendum

FISH RESULTS

There is amplification of the HER-2 /neu gene as determined by FISH,
(PathVysion assay). The ratio of the number of copies of the
HER-2/neu

gene to the centromeric probe for chromosome 17 is approximately 8. A
minimum of 25 cells were counted.

[page 4 of 16]
Component

The PathVysion assay kit by [REDACTED] is approved by FDA for HER-2 FISH assay.

All tissue used to provide diagnostic predictive information is fixed in 10% neutral buffered formalin and processed in paraffin.

Results reported as HER-2/neu: chromosome 17 centromere probe signal ratio

Reference Range(s)

Not amplified less than 1.8
Equivocal 1.8-2.2
Amplified greater than 2.2

Breast Marker Reference Ranges

Marker	Negative	Positive
ER	<1%	1% or higher
PR	<1%	1% or higher
Her-2/neu	0 or 1+	2+ or 3+
EGFR	<10%	10% or higher

Marker	Unfavorable	Intermediate	Favorable
MIB-1 (Ki-67)	>20%	10% to 20%	<10%

All tissue submitted to provide diagnostic predictive information is fixed in 10% neutral buffered formalin and processed in paraffin.

Immunohistochemistry controls are examined and show appropriate reactivity.

GROSS DESCRIPTION

A. Received from [REDACTED] are 10 unstained slides labeled [REDACTED] for patient [REDACTED] from [REDACTED] +0

SPECIMEN(S) RECEIVED

A: OS Case# [REDACTED]

* The above listed tests (if any) were developed and the performance characteristics determined by [REDACTED] Department of Pathology. These tests

[page 5 of 16]
Component

have

not been cleared or approved for commercial use by the U.S. Food and Drug Administration. The FDA has determined that FDA review is not required for such in-house assays. (21 CFR 809.30(e))

INTRADEPARTMENT CONSULTATION PATHOLOGIST: QA COMMITTEE
ICD-CM(s): 174.9

The attending pathologist was physically present when this specimen was diagnosed, and actively participated in all key decisions.

Lab and Collection

PATHOLOGY SURGICAL

- Lab and Collection Information

View Smartlink Info

+41

PATHOLOGY SURGICAL

Patient Release Status:

+41

This result is not viewable by the patient.

Order Report

☒ Order Details

Order Barcode

Click to view Order Barcode

[page 6 of 16]
[REDACTED]

[REDACTED]

MyChart Results Release

MyChart Status: Pending

Patient Release Status:

This result is not viewable by the patient.

[REDACTED]

Procedure: CT CHEST WITHOUT AND WITH IV CONTRAST
Exam Date & Time: [REDACTED] +22
Status: Final

Patient: [REDACTED]
DOB: [REDACTED]
Sex: Female
Pt Class:
Location: [REDACTED]

MRN #: [REDACTED]
Order #: [REDACTED]
Accession #: [REDACTED]
Ord Prov: [REDACTED]

NARRATIVE:

CT CHEST WITH CONTRAST-PE PROTOCOL
CT CHEST WITH AND WITHOUT IV CONTRAST

DATE: [REDACTED] +22

INDICATION: Breast cancer, shortness of breath, assess for chemotherapy induced pneumonitis

COMPARISON: None.

TECHNIQUE: Following intravenous infusion of 100 mL of Isovue 370, 1.5 mm axial acquisitions were obtained. Coronal MPR images were generated. High resolution images in expiration and inspiration were also obtained.

This CT scan was performed with attention to patient radiation dose reduction, as low as reasonably achievable (ALARA), while maintaining diagnostic imaging quality. This includes appropriate physician-selected protocols to tailor the exam for minimum exposure and utilization of an active dose reduction device according to body habitus (Philips "Dose Right ACS" or GE "Smart mAs"), or manual mAs selection (Siemens).

FINDINGS:

[page 7 of 16]
The apparent filling defect in the right upper lobe segmental artery (image 73 of series 4 and image 46 of series 601b) is believed to be artifactual secondary to volume averaging artifact from the right hilar lymph nodes and adjacent superior segmental pulmonary veins. Otherwise, no filling defects are seen within the pulmonary vasculature to the level of the segmental arteries. Heart size is mildly enlarged. There is no pericardial effusion. The tip of the left IJ approach central line is at the cavoatrial junction.

About 4 partially calcified lung nodules are present in the right lung; largest is seen in the right lower pole measuring 1.2 cm. Subcentimeter calcified right paratracheal and right hilar lymph nodes are also seen. There is pleural based 0.8-cm nodule in left upper lobe (image 65 of series 5).

Several mildly prominent noncalcified lymph nodes are noted in the AP window and right hilum. The largest measures 1.4 x 0.5 cm.

Small right pleural effusion is present with associated compressive atelectasis of the right lower lobe. Trace left pleural effusion or pleural thickening is seen. There is no pneumothorax.

High resolution images do not show evidence of fibrosis, bronchiectasis or septal thickening. Linear opacities in the right middle lobe and left lower lobe are consistent with subsegmental atelectasis.

There is a right breast mass measuring 7.0 x 5.1 cm. Several enlarged right axillary lymph nodes are seen, the largest measures 2.6 x 1.7 cm.

There is a 2.6 x 1.5 cm right thyroid cystic lesion.

There are subcentimeter sclerotic lesions in the vertebral bodies at T5, T7, T8, T10 and T12. Remaining thoracic vertebral bodies have ill-defined faint sclerotic areas.

Postcholecystectomy clips are seen. There are calcified benign granulomas in the spleen. The linear calcific densities at the anterior lateral margin of the spleen are of doubtful clinical significance. The origin of the celiac artery is severely narrowed.

IMPRESSION:

1. No evidence of pulmonary embolism to the level of the segmental arteries. An apparent filling defect within the right upper lobe segmental pulmonary artery due to volume averaging artifact from adjacent hilar lymph nodes and superior pulmonary veins.
2. Several calcified right pulmonary nodules with calcified right paratracheal and hilar lymph nodes are sequela of prior granulomatous infection.
3. Subpleural left pulmonary nodule is nonspecific.
4. Small right pleural effusion with subsegmental atelectasis of the right lower lobe.
5. Sclerotic bone lesions in the thoracic spine, concerning for osseous metastasis. Consider further evaluation with bone scan.

[page 8 of 16]
6. Right thyroid lobe 2.6 x 1.5 cm cystic lesion. Consider further evaluation with ultrasound of the thyroid.

7. Large right breast mass consistent with malignancy. Multiple enlarged right axillary lymph nodes representing metastatic tumor in lymph nodes.

8. Severe narrowing at the origin of the celiac artery.

I, [REDACTED] have personally reviewed and interpreted the images of this study. In addition, I have personally reviewed this report and concur with its findings and conclusions as affirmed by my electronic signature.

Resident/Fellow [REDACTED] +22

Attending [REDACTED] +23

Electronically Signed By [REDACTED] +23

Order Report

[Order Details](#)

Order Barcode

[Click to view Order Barcode](#)

[page 9 of 16]
[REDACTED]

[REDACTED]

Patient Release Status:

This result is not viewable by the patient.

[REDACTED]

Procedure: CT CHEST, ABDOMEN & PELVIS WITH IV CONTRAST
Exam Date & Time: [REDACTED]
Status: Final +407

Patient: [REDACTED]
DOB: [REDACTED]
Sex: [REDACTED]
Pt Class: [REDACTED]
Location: [REDACTED]

MRN #: [REDACTED]
Order #: [REDACTED]
Accession: [REDACTED]
Ord Prov: [REDACTED]

NARRATIVE:

EXAM:
CT CHEST, ABDOMEN AND PELVIS WITH IV CONTRAST [REDACTED] +407

HISTORY:
Breast cancer.

COMPARISON:
CT chest, abdomen, and pelvis [REDACTED] +328

TECHNIQUE:
No oral contrast was administered. During dynamic infusion of 125 ml of Isovue 370, contiguous 3 mm sections were obtained through the chest with 5 mm sections through the abdomen and pelvis. Delayed imaging of the abdomen and pelvis was also obtained. Additional longitudinal reformatted images were created. Bilateral breast shields were used.

This CT scan was performed with attention to patient radiation dose reduction, as low as reasonably achievable (ALARA), while maintaining diagnostic imaging quality. This includes appropriate physician-selected protocols to tailor the examination for minimum exposure and utilization of an active dose reduction device according to body habitus.

FINDINGS:

Chest:

A 2.5 x 3.8 cm right breast mass previously measured 4.3 x 3.7 cm.

A stable lobulated 2.3 x 1.2 cm lesion is noted in the right thyroid lobe.

[page 10 of 16]
[REDACTED]

No enlarged mediastinal, supraclavicular, axillary, hilar lymph nodes. There are multiple calcified hilar, and mediastinal lymph nodes.

Heart is stable in size. Mild atherosclerotic calcification is noted in the aortic arch. Aortic valvular calcification is also present. Redemonstrated is complete absence of the pericardium, with lung interposition between the aorta and pulmonary artery, and left-sided shift and rotation of the heart.

There are stable calcified pulmonary nodules, suggestive of granuloma is. No new pulmonary nodules are noted.

There multiple sclerotic lesions within the thoracic spine and ribs, consistent with metastatic disease. There are multiple bilateral rib fractures.

Abdomen and pelvis:

Stable calcified granulomas are noted in the spleen. There is stable lateral splenic capsular calcification. The gallbladder is surgically absent. The liver, adrenal glands, and pancreas have normal contrast enhanced CT appearance. The kidneys demonstrate symmetrical uptake in excretion of IV contrast. No hydronephrosis is noted.

No dilated or abnormally thickened bowel loops are present.

Within the pelvis, the bladder is decompressed. The uterus is present.

Abdominal aorta is non aneurysmal but has mild intimal wall calcification. There are no enlarged retroperitoneal, iliac chain, or inguinal lymph nodes. There is stable severe narrowing or atresia of the celiac axis.

Stable sclerotic lesions are noted in the abdomen and pelvis. Stable mild height loss of the L1 vertebral body.

IMPRESSION:

1. Interval decrease in size of the right breast mass.
2. Stable calcified pulmonary granulomas, and calcified mediastinal and hilar lymph nodes, and splenic granuloma, suggestive of old healed granulomatous disease.
3. Stable sclerotic osseous lesions in the chest, abdomen, and pelvis.
4. Congenital pericardial absence is again noted. Stable severe narrowing or atresia of the celiac axis. Aortic valvular calcification.
5. Hypodense right thyroid lesion. Thyroid ultrasound if not previously obtained is recommended.

I, [REDACTED] have personally reviewed and interpreted the images of this study. In addition, I have personally reviewed this report and concur with its findings and conclusions, as affirmed by my electronic signature.

Resident/Fellow [REDACTED] +407

Attending: [REDACTED] +407

Electronically Signed By: [REDACTED] +407

Order Report

[page 11 of 16]
Order Details

Order Barcode

[Click to view Order Barcode](#)

[page 12 of 16]
[REDACTED]

[REDACTED]

Patient Release Status:

This result is not viewable by the patient.

[REDACTED]

Procedure: CT CHEST, ABDOMEN & PELVIS WITH IV CONTRAST
Exam Date & Time: [REDACTED] +1292
Status: Final

Patient: [REDACTED]
DOB: [REDACTED]
Sex: [REDACTED]
Pt Class: [REDACTED]
Location: [REDACTED]

MRN #: [REDACTED]
Order #: [REDACTED]
Accession #: [REDACTED]
Ord Prov: [REDACTED]

NARRATIVE:

EXAM:
CT CHEST, ABDOMEN AND PELVIS WITH IV CONTRAST, [REDACTED] +1292

HISTORY:
Re-staging, metastatic breast ca Bone metastasis

COMPARISON:
CT chest abdomen pelvis [REDACTED] +1119

TECHNIQUE:
During dynamic infusion of 125 ml of Isovue 370, contiguous 2.5 mm sections were obtained through the chest with 5 mm sections through the abdomen and pelvis. Delayed images were obtained. Additional longitudinal reformatted images were created.

The CT scan was performed with attention to patient radiation dose reduction, as low as reasonably achievable (ALARA), while maintaining diagnostic image quality. At least one of the following dose reduction techniques was used: Automated exposure control, adjustment of the mA and/or kV according to patient size, use of iterative reconstruction technique.

FINDINGS:
CHEST:

Lungs and central airways: The central airways are patent. No focal consolidation. Mild biapical pleural scarring. Redemonstrated multiple calcified and partially calcified pulmonary nodules, which are stable in size. Represents example includes a partially calcified nodule in the posterior right lower lobe measuring 1.3 x 1.1 cm (series 3, image 58).

[page 13 of 16]
Pleura/Pleural Space: No pleural effusion

Mediastinum and Hila: Redemonstrated partially calcified mediastinal and hilar lymph nodes. No enlarged mediastinal or hilar lymph nodes.

Heart and pericardium: Heart is normal in size. There is lung tissue interposed between the main pulmonary artery and the ascending aorta with prominent levo position of the heart, which may be seen with pericardial agenesis, and has been stable since at least [REDACTED] +22

Vessels: No thoracic aortic aneurysm.

Bones: Approximately stable scattered sclerotic osseous metastases. Multilevel degenerative spondylosis.

Chest Wall: Interval increased size of a right axillary lymph node measuring 2.1 x 1.4 cm (series 2, image 23), previously 1.0 x 0.9 cm. Minimally increased right axillary ill-defined fat stranding. Approximately stable nodular soft tissue thickening within right superior breast (series 2, image 36).

Lower Neck: Stable solid and cystic right thyroid lobe nodule measuring at least 2 cm, unchanged since [REDACTED] +0

Support Devices: Left chest Port-A-Cath with tip terminating in the cavoatrial junction.

ABDOMEN/PELVIS:

Liver and gallbladder: Liver appears unremarkable. Gallbladder is surgically absent.

Pancreas, spleen, and adrenal glands: Scattered splenic calcified granulomas with more linear subcapsular splenic calcifications are redemonstrated. Pancreas and adrenal glands are unremarkable.

Kidneys, ureters, bladder, pelvis: Kidneys are symmetric without hydronephrosis or hydroureter. No perinephric stranding or enhancing renal mass. Urinary bladder is unremarkable. The uterus is present.

GI tract: Evaluation is limited without oral contrast. Stomach appears unremarkable. No bowel obstruction. Uncomplicated sigmoid diverticulosis.

Vessels/lymph nodes: Abdominal aorta is non aneurysmal with mild calcifications. No enlarged lymph nodes. No free fluid or free air.

Soft tissues/bones: Small umbilical fat containing hernia. Mild compression deformity of the L1 vertebral body. Approximately stable scattered sclerotic osseous metastasis. Edematous severe bilateral hip degenerative changes.

IMPRESSION:

1. Significant increased size of a right axillary lymph node. Mild increased right axillary fat stranding.
2. Stable right breast nodular soft tissue thickening.
3. Stable pulmonary nodules.
4. Stable osseous metastases. Stable mild L1 compression deformity.

[page 14 of 16]
[REDACTED] [REDACTED]
I [REDACTED] have personally reviewed and interpreted the images of this study.
In addition, I have personally reviewed this report and concur with its findings and conclusions,
as affirmed by my electronic signature.

Resident/Fellow: [REDACTED] +1292

Attending [REDACTED] +1292

Electronically Signed By: [REDACTED] +1292

Order Report

[Order Details](#)

Order Barcode

[Click to view Order Barcode](#)

[page 15 of 16]
██████████ BL imaging = Day 22

(BL = date of baseline imaging compared to date of first therapy that led to exceptional response.)

[page 16 of 16]
Level 1 case

Invasive ductal RT breast Cancer that improves after 1 year, then resolves at BL + 3.5 years

Axial and sagittal CT images
BL = Day 22 (upper row),
67 x 52 x 62 mm RT breast mass (arrows and measured)
BL + 1 year = Day 407 (middle row), RT breast mass is smaller (arrow)
BL + 3.5 years = Day 1295 (lower row), RT breast mass no longer noted (bone window)

Source: NCI Genomic Data Commons file fe424ea5-a40d-46bc-a73f-751dfd45f911 (ER0512 ER-B1T5 Clinical Report_Redacted_Sanitized.pdf), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).